Somatic mutation profile of tumor specimen TCGA-SS-A7HO-01A (aliquot TCGA-SS-A7HO-01A-21D-A36X-10) from TCGA case TCGA-SS-A7HO, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIB; Age at diagnosis: 44.9 years (16,416 days).
Specimen TCGA-SS-A7HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d44f30c2-5aa2-4c2b-97d7-2ba2a6ea545e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SS-A7HO-10A (Blood Derived Normal), aliquot TCGA-SS-A7HO-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46ad9a86-9c4d-4b7c-9f21-eb1c7133d662

The open-access MAF lists 180 somatic variants for this specimen: 132 protein-altering or splice-affecting, 42 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 42, Nonsense Mutation 12, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 2, RNA 2, Intron 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 133/148 reads (90%) | catalogued as rs775126020, CM980087, COSV57320525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4645C>T p.Q1549* | Nonsense Mutation (SNP) | VAF 138/158 reads (87%) | catalogued as rs863225357, COSV57334229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 85/172 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYO15A | c.1185dup p.E396Rfs*36 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 48/56 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.4957C>T p.R1653* | Nonsense Mutation (SNP) | VAF 135/239 reads (56%) | catalogued as rs754768875, CM080609, COSV100239697; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs140339167; called by muse, mutect2, varscan2
- ACVR2A | c.1337A>C p.Q446P | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV99605258; called by muse, mutect2, varscan2
- AGO4 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV100943126; called by muse, mutect2, varscan2
- AMIGO1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV100881119; called by muse, mutect2, varscan2
- AMOTL1 | c.2689G>A p.G897S | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs750475731, COSV100504811; called by muse, mutect2, varscan2
- AP4E1 | c.401T>A p.L134H | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99957308; called by muse, mutect2, varscan2
- APC | c.8209G>C p.E2737Q | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.596); catalogued as COSV57381899, COSV99970821; called by muse, mutect2, varscan2
- APLP1 | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV55706133, COSV99697999; called by muse, mutect2, varscan2
- ARFGEF2 | c.4042C>T p.R1348* | Nonsense Mutation (SNP) | VAF 23/146 reads (16%) | catalogued as COSV100904539; called by muse, mutect2, varscan2
- ARHGAP20 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs1191601571, COSV99503947, COSV99505675; called by muse, mutect2, varscan2
- ARHGAP36 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 62/85 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1200019083, COSV52267262; called by muse, mutect2, varscan2
- ARHGEF17 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs769389453, COSV99737068; called by muse, mutect2, varscan2
- ARID2 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 220/530 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.069); catalogued as COSV100537179; called by muse, mutect2, varscan2
- ARSL | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776323240, COSV66964826; called by muse, mutect2, varscan2
- ASMT | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 240/832 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs189062200, COSV101172411; called by muse, mutect2, varscan2
- ASXL2 | c.3206C>T p.T1069I | Missense Mutation (SNP) | VAF 9/269 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99712228; called by muse, mutect2
- BCO1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as rs568154975, COSV50731214; called by muse, mutect2, varscan2
- BLM | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs146096923, COSV61927363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP7 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 228/248 reads (92%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs776230892, COSV67782177; called by muse, mutect2, varscan2
- C8orf58 | c.1072C>T p.R358* (on ENST00000289989 / NM_001013842.3; = p.R350* on NM_173686.3) | Nonsense Mutation (SNP) | VAF 60/148 reads (41%) | catalogued as rs371650009; called by muse, mutect2
- CCNT2 | c.821A>T p.E274V | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99751305; called by muse, mutect2, varscan2
- CDKL4 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101115582; called by muse, mutect2, varscan2
- CHRM3 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776861962, COSV55080950; called by muse, mutect2, varscan2
- CHRM5 | c.766T>A p.C256S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.793); catalogued as COSV101272075; called by muse, mutect2, varscan2
- CHRNA1 | c.1388G>T p.C463F (on ENST00000261007 / NM_001039523.3; = p.C438F on NM_000079.4) | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99650793; called by muse, mutect2, varscan2
- COL1A2 | c.3859A>G p.K1287E | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99801436; called by muse, mutect2, varscan2
- COX10 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs372982577; called by muse, mutect2, varscan2
- CP | c.2582T>A p.I861N | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224557; called by muse, mutect2, varscan2
- CPNE7 | c.1610G>C p.R537P | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV99255203; called by muse, mutect2, varscan2
- CS | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100673311; called by muse, mutect2, varscan2
- CYP17A1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 48/186 reads (26%) | catalogued as COSV100882155; called by muse, mutect2, varscan2
- DAB2IP | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.191); catalogued as COSV99406543; called by muse, mutect2, varscan2
- DAOA | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as COSV100298764, COSV100298944, COSV61601544; called by muse, mutect2, varscan2
- DDX60L | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.16); catalogued as COSV99488679; called by muse, mutect2
- DIP2B | c.2425G>T p.V809F | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99999628; called by muse, mutect2, varscan2
- ENPP7 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs574138520, COSV60385770; called by muse, mutect2, varscan2
- F5 | c.4487C>T p.P1496L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs746632171, COSV100889285; called by muse, mutect2, varscan2
- FNBP4 | c.2955G>T p.Q985H | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99772059; called by muse, mutect2, varscan2
- FOXD4L3 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs1387660925, COSV100731045; called by muse, mutect2, varscan2
- FRMPD1 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 32/147 reads (22%) | catalogued as COSV100899674, COSV100899693; called by muse, mutect2, varscan2
- GKAP1 | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 111/143 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV100897769; called by muse, mutect2, varscan2
- GRM2 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1447545792, COSV99623248; called by muse, mutect2, varscan2
- HDAC6 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 79/131 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491351; called by muse, mutect2, varscan2
- HIBCH | c.260A>T p.K87M | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100676323; called by muse, mutect2, varscan2
- HOXD4 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 77/144 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV60459274; called by muse, mutect2, varscan2
- HSF1 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs782798876, COSV101275175; called by muse, mutect2, varscan2
- HUNK | c.1396C>A p.Q466K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV99529056; called by muse, mutect2, varscan2
- IL5RA | c.228+1G>A p.X76_splice | Splice Site (SNP) | VAF 132/311 reads (42%) | catalogued as rs775911773, COSV56521995; called by muse, mutect2, varscan2
- INPPL1 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99996749; called by muse, mutect2, varscan2
- INSYN2A | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99733467; called by muse, mutect2, varscan2
- ITIH2 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.204); catalogued as COSV100623476; called by muse, mutect2, varscan2
- KIAA1109 | c.7844A>C p.D2615A | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV99191739; called by muse, mutect2, varscan2
- LAMB1 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99741878; called by muse, mutect2, varscan2
- LIM2 | c.457G>A p.A153T (on ENST00000596399 / NM_001161748.2; = p.A195T on NM_030657.4) | Missense Mutation (SNP) | VAF 88/101 reads (87%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as rs1482585775, COSV55742660; called by muse, mutect2, varscan2
- LRP2 | c.11551A>T p.N3851Y | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790653; called by muse, mutect2, varscan2
- LRP3 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs760569914, COSV53507892; called by muse, mutect2, varscan2
- LRRFIP1 | c.899G>C p.S300T (on ENST00000392000 / NM_001137552.2; = p.S276T on NM_004735.4) | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99791382; called by muse, mutect2, varscan2
- MAP1A | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs763883565, COSV100289388; called by muse, mutect2, varscan2
- MAP3K5 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100753388; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM6 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); catalogued as rs767037709, COSV51468290; called by muse, mutect2, varscan2
- MDGA1 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752344272, COSV51804157; called by muse, mutect2, varscan2
- MED25 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as rs145507089; called by muse, mutect2, varscan2
- MUC16 | c.15746C>A p.T5249K | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV101202088; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- NTAQ1 | c.234+1G>T p.X78_splice | Splice Site (SNP) | VAF 102/254 reads (40%) | catalogued as rs763398571, COSV99783527; called by muse, mutect2, varscan2
- OR10G9 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as rs772344586, COSV100901801; called by muse, mutect2, varscan2
- OR10Z1 | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 91/168 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs750012091, COSV100779105, COSV63525241; called by muse, mutect2, varscan2
- OR1J1 | c.714G>T p.L238F | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.168); catalogued as rs754719556, COSV99403278; called by muse, mutect2, varscan2
- OR2G3 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180809; called by muse, mutect2, varscan2
- PANX1 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 47/102 reads (46%) | catalogued as COSV99922098; called by muse, mutect2, varscan2
- PCDH11X | c.1109T>C p.L370P | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016041; called by muse, mutect2, varscan2
- PCDHGA8 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 78/87 reads (90%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); catalogued as COSV54016635, COSV99548902; called by muse, mutect2, varscan2
- PCDHGB3 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54030922; called by muse, mutect2, varscan2
- PHRF1 | c.1520G>A p.G507D (on ENST00000264555 / NM_001286581.2; = p.G506D on NM_020901.4) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213798; called by muse, mutect2, varscan2
- PPEF1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 135/496 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV100584110; called by muse, mutect2, varscan2
- PPP1R10 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100919980; called by muse, mutect2, varscan2
- PPP6C | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV101001275; called by muse, mutect2, varscan2
- PREX2 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139157434; called by muse, mutect2, varscan2
- PRKCB | c.1810G>T p.D604Y | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100335625, COSV57802342; called by muse, mutect2, varscan2
- PTH2R | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs183627553, COSV55914770, COSV55920564; called by muse, mutect2, varscan2
- PTPRB | c.4295T>A p.M1432K | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV99719369; called by muse, mutect2, varscan2
- RIMS1 | c.181A>C p.M61L | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99331283; called by muse, mutect2, varscan2
- RIMS1 | c.1945C>A p.H649N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99331285; called by muse, mutect2, varscan2
- RNF39 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54993198, COSV99748794; called by muse, mutect2, varscan2
- RNF6 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 99/283 reads (35%) | catalogued as COSV100644696; called by muse, mutect2, varscan2
- RWDD1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.412); catalogued as COSV100888299; called by muse, mutect2, varscan2
- SCARA3 | c.1815C>A p.F605L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV100107102; called by muse, mutect2, varscan2
- SCN10A | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 113/252 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.852); catalogued as rs763455818, COSV101479569; called by muse, mutect2, varscan2
- SCN2A | c.2383A>T p.N795Y | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99331774; called by muse, mutect2, varscan2
- SCT | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs939252990, COSV99449366; called by muse, mutect2, varscan2
- SCUBE3 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as COSV99235356; called by muse, mutect2, varscan2
- SH2D4B | c.884G>A p.R295H (on ENST00000646907; = p.R294H on NM_207372.2) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs773391724, COSV100214313, COSV57900459; called by muse, mutect2, varscan2
- SIX1 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV99903376; called by muse, mutect2, varscan2
- SLC2A8 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs767054400, COSV100972724; called by muse, mutect2, varscan2
- SLC6A19 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as rs894693588, COSV100443598; called by muse, mutect2, varscan2
- SLC9A8 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 91/584 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs199598441, COSV100846355, COSV64288607; called by muse, mutect2, varscan2
- SNX14 | c.905A>G p.D302G (on ENST00000314673 / NM_001350535.1; = p.D258G on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV100121831; called by muse, mutect2, varscan2
- SPINK2 | c.156T>G p.C52W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50534538, COSV99954313; called by muse, mutect2, varscan2
- SPTBN4 | c.2537G>A p.G846E | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.491); catalogued as rs1027709688, COSV100152391; called by muse, mutect2, varscan2
- STK32B | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99287758; called by muse, mutect2, varscan2
- SUPT6H | c.5066G>A p.R1689Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as COSV99973175; called by muse, mutect2
- TFDP1 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946060; called by muse, mutect2, varscan2
- TGFB1 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs142642007; called by muse, mutect2, varscan2
- TNC | c.83T>A p.V28D | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100406442; called by muse, mutect2, varscan2
- TP73 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV60704915; called by muse, mutect2, varscan2
- TRAK2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs553149082, COSV100217212; called by muse, mutect2, varscan2
- TRAPPC9 | c.1286A>T p.Y429F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV101228530; called by muse, mutect2, varscan2
- TRPC1 | c.1582A>C p.I528L (on ENST00000476941 / NM_001251845.2; = p.I494L on NM_003304.4) | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV99859445; called by muse, mutect2, varscan2
- TRPC3 | c.2731G>T p.E911* (on ENST00000379645 / NM_001366479.2; = p.E838* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 97/170 reads (57%) | catalogued as COSV53371789; called by muse, mutect2, varscan2
- TTC38 | c.745A>T p.M249L | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV101123960; called by muse, varscan2
- TUBG2 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs968062942, COSV52216912; called by muse, mutect2
- UNC13C | c.2351G>A p.S784N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99523986; called by muse, mutect2, varscan2
- UNC5C | c.1595C>G p.A532G | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV101498071, COSV71661602; called by muse, mutect2, varscan2
- VENTX | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100384166; called by muse, mutect2, varscan2
- VMP1 | c.812T>A p.F271Y | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99231089; called by muse, mutect2, varscan2
- WASHC4 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs190348595, COSV59889967; called by muse, mutect2, varscan2
- WDR13 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 125/206 reads (61%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.972); catalogued as COSV99489669; called by muse, mutect2, varscan2
- ZBED4 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs753177858, COSV99351838; called by muse, mutect2, varscan2
- ZNF227 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs746533904, COSV57313853; called by muse, mutect2, varscan2
- BCOR | c.3643dup p.R1215Kfs*30 (on ENST00000378444 / NM_001123385.2; = p.R1181Kfs*30 on NM_017745.6) | Frame Shift Ins (INS) | VAF 64/489 reads (13%) | called by mutect2, pindel, varscan2
- BSN | c.1533_1534del p.C512Sfs*85 | Frame Shift Del (DEL) | VAF 92/252 reads (37%) | called by pindel, varscan2
- IGHV1OR15-9 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ITGA5 | c.897_900del p.Y300Afs*75 | Frame Shift Del (DEL) | VAF 40/93 reads (43%) | called by mutect2, pindel, varscan2
- POLQ | c.6853del p.Y2285Ifs*7 | Frame Shift Del (DEL) | VAF 51/141 reads (36%) | called by mutect2, pindel, varscan2
- SLCO6A1 | c.1572_1573insG p.F525Vfs*12 | Frame Shift Ins (INS) | VAF 76/388 reads (20%) | called by mutect2, varscan2
- ADAMTS12 | c.1074C>T p.C358= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs764423821, COSV100711769; called by muse, mutect2, varscan2
- ANXA13 | c.801G>A p.T267= | Silent (SNP) | VAF 61/122 reads (50%) | catalogued as rs369931826; called by muse, mutect2, varscan2
- ASB15 | c.1281C>T p.N427= | Silent (SNP) | VAF 70/189 reads (37%) | catalogued as rs769692009, COSV99307077; called by muse, mutect2, varscan2
- C1QTNF9B | c.456C>A p.G152= | Silent (SNP) | VAF 52/226 reads (23%) | catalogued as COSV101158651, COSV65944376; called by muse, mutect2, varscan2
- C5AR1 | c.900C>T p.Y300= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs140534066; called by muse, mutect2, varscan2
- C7orf57 | c.298C>T p.L100= | Silent (SNP) | VAF 81/157 reads (52%) | catalogued as COSV100817318, COSV100817337; called by muse, mutect2, varscan2
- CALCRL | c.978G>A p.A326= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as rs758095114, COSV101131053; called by muse, mutect2, varscan2
- CD1E | c.531T>C p.D177= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100937089; called by muse, mutect2, varscan2
- CHRD | c.228C>T p.R76= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs9880198, COSV99200923; called by muse, varscan2
- CNTN5 | c.1674T>C p.G558= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV99682319; called by muse, mutect2, varscan2
- DDX23 | c.774C>A p.I258= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV100340017; called by muse, mutect2
- DGCR2 | c.774C>T p.Y258= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs146689556; called by muse, mutect2, varscan2
- DLG4 | c.1638C>T p.R546= (on ENST00000399506 / NM_001321075.3; = p.R589= on NM_001365.4) | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as rs201604329, COSV100264077; called by muse, mutect2, varscan2
- EP400 | c.3945C>T p.S1315= | Silent (SNP) | VAF 85/164 reads (52%) | catalogued as rs540244111, COSV100202527; called by muse, mutect2, varscan2
- FAM83C | c.255G>T p.V85= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100981750; called by muse, mutect2, varscan2
- FNBP4 | c.2956C>T p.L986= | Silent (SNP) | VAF 115/252 reads (46%) | catalogued as COSV99772057; called by muse, mutect2, varscan2
- FRY | c.4863C>T p.A1621= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as COSV100970030; called by muse, mutect2, varscan2
- GRIK1 | c.2244C>T p.Y748= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs369936597, COSV58711063; called by muse, mutect2, varscan2
- HLF | c.732C>T p.D244= | Silent (SNP) | VAF 47/208 reads (23%) | catalogued as rs532337710, COSV56832511; called by muse, mutect2, varscan2
- HSPA12A | c.606G>A p.T202= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs367814906; called by muse, mutect2, varscan2
- HTR3B | c.729C>T p.V243= | Silent (SNP) | VAF 59/116 reads (51%) | catalogued as rs1032116392, COSV99492395; called by muse, mutect2, varscan2
- INSYN2A | c.414C>T p.S138= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as COSV99733464; called by muse, mutect2, varscan2
- ITGAD | c.1044C>T p.H348= | Silent (SNP) | VAF 28/30 reads (93%) | catalogued as rs367975812; called by muse, mutect2, varscan2
- JAK3 | c.147G>A p.L49= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as COSV101513042; called by muse, mutect2, varscan2
- JHY | c.2190T>A p.T730= | Silent (SNP) | VAF 80/178 reads (45%) | catalogued as COSV99913907; called by muse, mutect2, varscan2
- JPH3 | c.969C>T p.Y323= | Silent (SNP) | VAF 35/37 reads (95%) | catalogued as rs376157795; called by muse, mutect2, varscan2
- KLC2 | c.1575C>T p.D525= | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as rs539580481, COSV57582610; called by muse, mutect2, varscan2
- LAMC3 | c.174C>T p.P58= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100736128; called by muse, mutect2, varscan2
- NELL2 | c.768T>C p.S256= | Silent (SNP) | VAF 57/268 reads (21%) | catalogued as rs141434479; called by muse, mutect2, varscan2
- ODF2 | c.501C>T p.H167= (on ENST00000434106 / NM_153433.2; = p.H143= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs1319957124, COSV63548846; called by muse, mutect2, varscan2
- OR8B12 | c.615C>T p.D205= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs776638132, COSV60910985; called by muse, mutect2, varscan2
- PNMA1 | c.105C>T p.I35= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as rs376942172; called by muse, mutect2, varscan2
- PTGER3 | c.1200G>A p.E400= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV100657527; called by muse, mutect2, varscan2
- RELA | c.1395C>T p.D465= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100425977; called by muse, varscan2
- SLC38A7 | c.531G>A p.K177= | Silent (SNP) | VAF 94/108 reads (87%) | catalogued as rs1402515918, COSV99543991; called by muse, mutect2, varscan2
- SMPD4 | c.2502C>T p.V834= (on ENST00000409031 / NM_017951.4; = p.V805= on NM_017751.4) | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as rs767644066, COSV100302854; called by muse, mutect2, varscan2
- TENM3 | c.1857T>C p.C619= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV101305545; called by muse, mutect2, varscan2
- TJP1 | c.1660C>T p.L554= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as COSV100633257; called by muse, mutect2
- TMEM143 | c.117G>T p.G39= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV53157435, COSV99507613; called by muse, mutect2, varscan2
- TRIOBP | c.6873C>T p.N2291= (on ENST00000644935 / NM_001039141.3; = p.N578= on NM_007032.5) | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as rs768762605, COSV60377976; called by muse, mutect2, varscan2
- TSHZ3 | c.2661C>T p.P887= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs148165190; called by muse, mutect2, varscan2
- ZSWIM1 | c.108T>C p.N36= | Silent (SNP) | VAF 202/213 reads (95%) | catalogued as COSV99667076; called by muse, mutect2, varscan2
- AL136982.4 | n.1090del | RNA (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- ASS1 | c.773+67G>A | Intron (SNP) | VAF 37/88 reads (42%) | catalogued as rs777414511; called by muse, mutect2, varscan2
- COLCA2 | chr11:111296261 G>T | 5'Flank (SNP) | VAF 28/130 reads (22%) | catalogued as rs753063154; called by muse, mutect2, varscan2
- DCHS2 | n.7542G>C | RNA (SNP) | VAF 30/107 reads (28%) | catalogued as COSV100602835; called by muse, mutect2, varscan2
- DST | c.4297-4784T>C | Intron (SNP) | VAF 141/324 reads (44%) | catalogued as COSV99760839; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777624 C>T | 5'Flank (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100023089; called by muse, mutect2, varscan2
